Somatic mutation profile of tumor specimen C3N-02183-01 (aliquot CPT0168480006) from CPTAC case C3N-02183, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.6 years (23,246 days).
Specimen C3N-02183-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4102251e-5411-48ac-81c3-d95c31bbf000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02183-71 (Blood Derived Normal), aliquot CPT0168540004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f0dbd62-af0e-4fa5-9d05-046443a23eba

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Nonstop Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83H | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 21/443 reads (5%) | catalogued as rs137854439, CM087428, COSV66354019; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.5902C>T p.R1968* (on ENST00000358273 / NM_001042492.3; = p.R1947* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 17/200 reads (9%) | catalogued as rs137854552, CM900173, COSV62199973; ClinVar: pathogenic; called by muse, mutect2
- SUOX | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 304/440 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565799921; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACKR2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV56178689; called by muse, mutect2, varscan2
- CCDC149 | c.1273G>A p.A425T (on ENST00000635206 / NM_001330643.2; = p.A414T on NM_173463.5) | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as rs866274450; called by muse, mutect2
- CORO1C | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs754430834; called by muse, mutect2
- CPED1 | c.2929C>A p.H977N | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59999480; called by muse, mutect2
- DLG3 | c.1616C>T p.S539F (on ENST00000374360 / NM_021120.4; = p.S202F on NM_020730.3) | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99529148; called by muse, mutect2, varscan2
- EYS | c.1300-2A>T p.X434_splice | Splice Site (SNP) | VAF 12/179 reads (7%) | catalogued as COSV60987102; called by muse, mutect2
- LTBP4 | c.2224C>G p.R742G (on ENST00000308370 / NM_001042544.1; = p.R705G on NM_003573.2) | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.607); catalogued as COSV99180558; called by muse, mutect2
- MTMR3 | c.1813_1814insA p.L605Hfs*8 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | catalogued as COSV60304268; called by mutect2, pindel
- MYOM1 | c.4364T>C p.V1455A | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55288259; called by muse, mutect2
- NPAT | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778382186; called by muse, mutect2
- OR10A4 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV65841852; called by muse, mutect2
- PCDHA3 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.308); catalogued as rs782408810; called by muse, mutect2
- PPFIBP2 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs764792123; called by muse, mutect2
- RFX6 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.273); catalogued as rs1236879785; called by muse, mutect2
- RYR3 | c.1554C>A p.N518K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1431001801; called by muse, mutect2, varscan2
- SENP1 | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV50289339; called by muse, mutect2
- TEP1 | c.7298C>T p.P2433L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs762480078; called by muse, mutect2
- ZC3H12B | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.77); catalogued as rs1477656531, COSV100161712; called by muse, mutect2
- ACTR8 | c.770del p.G257Vfs*20 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | called by mutect2, pindel, varscan2
- C14orf39 | c.1764A>T p.*588Cext*4 | Nonstop Mutation (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- CEMIP2 | c.2512T>C p.Y838H | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CYP1A2 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.899); called by muse, mutect2
- EXOC3L4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- IGSF22 | c.1000A>G p.M334V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by mutect2, varscan2
- IL1RAPL2 | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.359); called by muse, mutect2
- MYH15 | c.4024del p.A1342Pfs*44 | Frame Shift Del (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel, varscan2
- PTPN3 | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ZNF699 | c.1052T>C p.I351T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP9A | c.1791G>A p.R597= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV58765963; called by muse, mutect2
- CARD9 | c.417C>T p.S139= | Silent (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2
- DSTYK | c.2775A>G p.L925= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- GPRC6A | c.1641C>T p.N547= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs369104625; called by muse, mutect2, varscan2
- MAOB | c.993C>T p.T331= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100956204; called by muse, mutect2
- MECP2 | c.1029G>A p.G343= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs1057522816, CD057803; called by muse, mutect2
- TBC1D25 | c.432C>A p.V144= | Silent (SNP) | VAF 11/288 reads (4%) | called by muse, mutect2
- UBR3 | c.804G>A p.Q268= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- CAPN5 | c.-36+6010C>T | Intron (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- CPED1 | c.2311-4532G>A | Intron (SNP) | VAF 19/322 reads (6%) | catalogued as COSV100120933; called by muse, mutect2
- MARVELD3 | chr16:71640440 A>G | 3'Flank (SNP) | VAF 18/135 reads (13%) | catalogued as rs1434477515; called by muse, mutect2, varscan2
- MS4A4A | c.41+1880G>T | Intron (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- TSC2 | c.1443+28G>A | Intron (SNP) | VAF 22/338 reads (7%) | catalogued as rs564986177; called by muse, mutect2
- ZBBX | c.1880-6450T>C | Intron (SNP) | VAF 12/151 reads (8%) | called by muse, mutect2
